Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5791, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5791-01A (Primary Tumor).

Diagnosis

1. Poorly differentiated, max. 2.3 cm, acinar adenocarcinoma of the prostate in both lobes with marked perineural growth along major nerves, limited to the prostate and with tumor-free seminal vesicles and seminal ducts.
2. Tumor-free fatty connective tissue. No malignancy.
3. Three tumor-free lipomatous lymph nodes. No malignancy.
4. Two tumor-free lipomatous lymph nodes. No malignancy.

Remark

Carcinoma infiltrates are found with apical predominance on both sides and left dorsolateral predominance in those parts of the prostate close to the apex. The preparation margin labeled green and blue is tumor-free.

In summary, the tumor classification is as follows: pT2c, pN0 (0/5), Gleason 3+4 = 7, Gleason 4: approx. 10%, G3, L0, V0.

Diagnosis

1. Tumor-free soft tissue.
2. Tumor-free soft tissue with vessels and nerves and parts of the seminal vesicle.
-

Source: NCI Genomic Data Commons file bdf52ef5-e398-4870-8edf-f37223747183 (TCGA-CH-5791.009BF26F-B3DF-4F10-B496-A4304AF1E091.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).